CCDI case PBBZAE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/2003e687-aa41-4dff-83c8-082f24c04ea4

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Pharynx, NOS; Age at diagnosis: 4.7 years (1,702 days).

Biospecimens (3 samples)
- Sample 0DLDZA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLDZG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLDZN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
